CCDI case PBCGLF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/03ba22e7-fe4b-4866-86f2-cc65b1ba2326

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 17.4 years (6,359 days).

Biospecimens (3 samples)
- Sample 0DRGEU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRXEH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRXEN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
